Somatic mutation profile of tumor specimen TCGA-QQ-A5VD-01A (aliquot TCGA-QQ-A5VD-01A-21D-A32I-09) from TCGA case TCGA-QQ-A5VD, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 52.0 years (19,004 days).
Specimen TCGA-QQ-A5VD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea25057-e26e-4d30-948c-a59e2b8d7299.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A5VD-10A (Blood Derived Normal), aliquot TCGA-QQ-A5VD-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/137a7920-bab3-46a3-a334-7290326dff74

The open-access MAF lists 456 somatic variants for this specimen: 306 protein-altering or splice-affecting, 149 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 266, Silent 149, Nonsense Mutation 24, Splice Site 7, Splice Region 5, Frame Shift Del 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC8 | c.551-1G>A p.X184_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | catalogued as rs1554073316, CS073474, COSV99410218; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLEKHG5 | c.884C>T p.P295L (on ENST00000400915 / NM_001042663.3; = p.P258L on NM_020631.6) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs910474236, COSV100556212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs1354030520, COSV57298415; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | hotspot (GDC flag); catalogued as rs137853293, CM900196, COSV57296164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as rs765061840, CM1413591, COSV99968154; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WNT7B | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1569119395, COSV100254803; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4621C>T p.Q1541* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100382730; called by muse, mutect2, varscan2
- ABCB4 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99709872; called by muse, mutect2, varscan2
- ABL1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104403972, COSV59342374; called by muse, mutect2, varscan2
- ABL2 | c.2050G>A p.E684K (on ENST00000502732 / NM_007314.4; = p.E669K on NM_005158.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV61012829; called by muse, mutect2, varscan2
- ACSM4 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV101257054; called by muse, mutect2, varscan2
- ACSM4 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV101257056; called by muse, mutect2, varscan2
- ACVR1B | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99231291; called by muse, mutect2
- ADAMTSL5 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867541463; called by muse, mutect2
- ADGRF5 | c.2047A>G p.I683V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV99345043; called by muse, mutect2, varscan2
- ADGRG3 | c.1456G>C p.V486L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as COSV100342123; called by muse, mutect2, varscan2
- ADGRV1 | c.7048G>A p.G2350S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315548; called by muse, mutect2
- AFF2 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53984343, COSV99662278; called by muse, mutect2, varscan2
- ANKS1B | c.3536G>A p.G1179E (on ENST00000547776 / NM_152788.4; = p.G345E on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227322; called by muse, mutect2, varscan2
- ANKS1B | c.3535G>A p.G1179R (on ENST00000547776 / NM_152788.4; = p.G345R on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227326, COSV59121305; called by muse, mutect2, varscan2
- ANKS1B | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243318; called by muse, mutect2
- ANKS1B | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243321; called by muse, mutect2
- ARAP2 | c.3694C>T p.L1232F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs922747029, COSV100394226; called by muse, mutect2, varscan2
- ARAP2 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141950924, COSV58293960; called by muse, mutect2, varscan2
- ARGLU1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as COSV100639746; called by muse, mutect2, varscan2
- ARHGEF16 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1208212397, COSV101000365; called by muse, mutect2, varscan2
- ASTN1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99920683; called by muse, mutect2
- ASXL3 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs267605172, COSV52457906; called by muse, mutect2, varscan2
- ATG3 | c.590C>G p.T197S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99343974; called by muse, mutect2
- ATP8B4 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV99464129; called by muse, mutect2, varscan2
- ATP8B4 | c.1675T>G p.S559A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52717165; called by muse, mutect2, varscan2
- BBS4 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as rs754792792, COSV51436976, COSV99166501; called by mutect2, varscan2
- BCL9 | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52342468; called by muse, mutect2, varscan2
- BLK | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.292); catalogued as COSV52051538; called by muse, mutect2, varscan2
- BTBD8 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV61546948; called by muse, mutect2, varscan2
- C9 | c.307A>G p.N103D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV99661752; called by muse, mutect2, varscan2
- CACNA1E | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100701397; called by muse, mutect2, varscan2
- CACNA1E | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100701398; called by muse, mutect2, varscan2
- CALCB | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100158032; called by muse, mutect2, varscan2
- CAPN3 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100532596; called by muse, mutect2, varscan2
- CASP4 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV101274116; called by muse, mutect2, varscan2
- CAVIN4 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100293138; called by muse, mutect2, varscan2
- CCNT2 | c.540-1G>C p.X180_splice | Splice Site (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99750242; called by mutect2, varscan2
- CDC25B | c.733G>A p.V245M (on ENST00000245960 / NM_021873.3; = p.V231M on NM_004358.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as rs1416292708, COSV99847672; called by muse, mutect2, varscan2
- CDH10 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100050338; called by muse, mutect2, varscan2
- CHERP | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.067); catalogued as COSV99550037; called by muse, mutect2
- CHERP | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV52224908; called by muse, mutect2
- CHL1 | c.1730C>T p.T577I (on ENST00000397491 / NM_001253387.1; = p.T593I on NM_006614.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.46); catalogued as COSV99850321; called by muse, mutect2, varscan2
- CLN3 | c.440C>T p.S147F (on ENST00000360019 / NM_001286104.2; = p.S171F on NM_000086.2) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1401497994, COSV100343091; called by muse, mutect2, varscan2
- CNGA2 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1478737457, COSV100323443; called by muse, mutect2
- CNTNAP5 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV70470072; called by mutect2, varscan2
- COL25A1 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211257, COSV101211349; called by muse, mutect2, varscan2
- COL6A3 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99796466; called by muse, mutect2, varscan2
- COL6A3 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777304407, COSV99796467; called by muse, mutect2, varscan2
- COL7A1 | c.7301G>A p.G2434E | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100095283; called by muse, mutect2
- COL7A1 | c.7300G>A p.G2434R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HM080096, COSV100095286; called by muse, mutect2
- COL7A1 | c.2317C>G p.P773A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); catalogued as COSV100095289; called by mutect2, varscan2
- COL7A1 | c.2316C>T p.A772= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100095292; called by muse, mutect2, varscan2
- COL9A1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as COSV57878200; called by muse, mutect2, varscan2
- COL9A3 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100101908; called by muse, mutect2, varscan2
- COLGALT2 | c.1241T>G p.F414C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100730447; called by muse, mutect2, varscan2
- CRY1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50483061; called by muse, mutect2, varscan2
- CSMD1 | c.9332G>A p.G3111E (on ENST00000520002; = p.G3110E on NM_033225.6) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59338867; called by muse, mutect2, varscan2
- CSMD1 | c.8744G>A p.G2915E (on ENST00000520002; = p.G2914E on NM_033225.6) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV59284780; called by muse, mutect2
- CSMD3 | c.10011G>A p.W3337* (on ENST00000297405 / NM_001363185.1; = p.W3168* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99826990; called by muse, mutect2, varscan2
- CSMD3 | c.10010G>C p.W3337S (on ENST00000297405 / NM_001363185.1; = p.W3168S on NM_052900.3) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52147148, COSV99826994, COSV99842873; called by muse, mutect2, varscan2
- CSMD3 | c.2606G>A p.G869E (on ENST00000297405 / NM_001363185.1; = p.G765E on NM_052900.3) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52185822, COSV99826995; called by muse, mutect2, varscan2
- CSMD3 | c.2605G>A p.G869R (on ENST00000297405 / NM_001363185.1; = p.G765R on NM_052900.3) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99826999; called by muse, mutect2, varscan2
- CST9L | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100980831, COSV100980916; called by muse, mutect2, varscan2
- CTNNA1 | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1297469358, COSV57069373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100242268; called by muse, mutect2, varscan2
- CUBN | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64701471; called by muse, mutect2, varscan2
- DCAF8L1 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101491409; called by muse, mutect2, varscan2
- DDX21 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs374486646, COSV100826477; called by muse, mutect2, varscan2
- DENND2A | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52048773, COSV99325637; called by muse, mutect2, varscan2
- DENND4A | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101475273; called by muse, mutect2, varscan2
- DHX32 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99501422; called by muse, mutect2, varscan2
- DHX34 | c.708C>T p.V236= | Splice Region (SNP) | VAF 5/21 reads (24%) | catalogued as rs753572284, COSV100169316; called by muse, mutect2
- DISP3 | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99607598; called by muse, mutect2
- DMRT1 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV101206622; called by muse, mutect2, varscan2
- DNAAF1 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.637); catalogued as COSV100533493; called by muse, mutect2
- DNAH17 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101101606; called by muse, mutect2, varscan2
- DNAJC10 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99898947; called by muse, mutect2, varscan2
- DOCK4 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101455463; called by muse, mutect2
- DQX1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs868404210, COSV99239492; called by muse, mutect2
- DUOX1 | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99334273; called by muse, mutect2, varscan2
- E2F4 | c.1004T>G p.F335C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100681463, COSV62607419; called by muse, mutect2, varscan2
- EFEMP1 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100816757; called by muse, mutect2, varscan2
- EFL1 | c.2372T>C p.M791T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs777324138, COSV99186433; called by muse, mutect2, varscan2
- EHD3 | c.966C>A p.F322L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100434636, COSV59029287; called by muse, mutect2, varscan2
- EIF2B3 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs1557696437, COSV100838909; called by muse, mutect2, varscan2
- EPB41L4A | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV54865906, COSV54878003; called by muse, mutect2, varscan2
- ERICH3 | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1365373663, COSV58605892; called by muse, mutect2, varscan2
- ESPL1 | c.4081C>T p.P1361S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99228973; called by muse, mutect2, varscan2
- ETS2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs147744979; called by muse, mutect2
- EVPL | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); catalogued as COSV100044079; called by muse, mutect2, varscan2
- EXPH5 | c.4346G>A p.G1449E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.331); catalogued as rs1451902562, COSV99761088; called by mutect2, varscan2
- EXTL3 | c.2313C>G p.F771L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV99593786; called by muse, mutect2, varscan2
- F11 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as rs1243512935, COSV99250711; called by muse, mutect2, varscan2
- FARSA | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108695; called by muse, mutect2, varscan2
- FAT2 | c.12127G>A p.D4043N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as rs775632768, COSV99941906; called by muse, mutect2, varscan2
- FAT2 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1341438777, COSV55814677, COSV99941913; called by muse, mutect2, varscan2
- FAT3 | c.4576C>G p.H1526D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99962783; called by muse, mutect2, varscan2
- FAT4 | c.4394G>A p.R1465K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.958); catalogued as rs776002583, COSV101272105; called by muse, mutect2, varscan2
- FBN2 | c.6253C>T p.P2085S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as rs34845843, CM148693, COSV99325473; called by muse, mutect2, varscan2
- FGF13 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.065); catalogued as COSV100263740; called by muse, mutect2, varscan2
- FLG2 | c.6815C>T p.S2272L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs554543735, COSV101165633; called by muse, mutect2, varscan2
- FNIP1 | c.2176G>A p.G726R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs367969091; called by muse, mutect2
- FRAS1 | c.5776C>T p.P1926S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1240186969, COSV99348912; called by muse, mutect2, varscan2
- FRAS1 | c.5777C>T p.P1926L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99348916; called by muse, mutect2, varscan2
- FREM2 | c.4030C>T p.R1344C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs114409305, COSV54831462; called by muse, mutect2, varscan2
- GALNT13 | c.1296G>A p.E432= | Splice Region (SNP) | VAF 12/69 reads (17%) | catalogued as COSV101222304; called by muse, mutect2, varscan2
- GALNT13 | c.1296+1G>A p.X432_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | catalogued as COSV101222305; called by muse, mutect2, varscan2
- GDAP2 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV101031862; called by muse, mutect2, varscan2
- GIT2 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100188853; called by muse, mutect2
- GLIS3 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1450686430, COSV100173421; called by muse, mutect2, varscan2
- GNAS | c.1790A>G p.N597S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100005582; called by muse, mutect2, varscan2
- GNE | c.1393T>A p.Y465N (on ENST00000396594 / NM_001128227.3; = p.Y434N on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as rs765843270, COSV100929894; called by muse, mutect2, varscan2
- GPR63 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1410261663, COSV100013178, COSV57742416; called by muse, mutect2, varscan2
- GRM7 | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100735861; called by muse, mutect2, varscan2
- GUCY2C | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as rs147742759; called by muse, mutect2, varscan2
- HCN4 | c.1977A>C p.G659= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99983376; called by muse, mutect2, varscan2
- HCN4 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99983378; called by muse, mutect2, varscan2
- HDC | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1228488372, COSV99983877; called by muse, mutect2, varscan2
- HEBP2 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV100874935; called by muse, mutect2, varscan2
- HGF | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs202185530, COSV99735880, COSV99737070; called by muse, mutect2, varscan2
- HINT2 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.414); catalogued as COSV99427865; called by muse, mutect2, varscan2
- HIVEP2 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs1376079429, COSV50011021, COSV99171552; called by muse, mutect2, varscan2
- HNF4A | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100291140; called by muse, mutect2, varscan2
- HPN | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV99384907; called by muse, mutect2, varscan2
- IFT172 | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV99561939; called by muse, mutect2
- IL36RN | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100697228; called by muse, mutect2, varscan2
- ITPR3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65406344; called by muse, mutect2, varscan2
- KCNK10 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100067712, COSV56639905; called by muse, mutect2, varscan2
- KCNK10 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100067717; called by muse, mutect2, varscan2
- KIAA0895 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.023); catalogued as COSV51714954; called by muse, mutect2, varscan2
- KIF16B | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); catalogued as rs778077073, COSV61717989; called by muse, mutect2
- KIF1C | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100296987, COSV100297288; called by muse, mutect2, varscan2
- KIF24 | c.3608G>A p.G1203E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99902912; called by muse, mutect2, varscan2
- KLHL30 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.134); catalogued as COSV100014038; called by muse, mutect2, varscan2
- KNL1 | c.1520A>G p.E507G (on ENST00000346991 / NM_170589.5; = p.E481G on NM_144508.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs759161231, COSV100706040; called by muse, mutect2, varscan2
- LAMA1 | c.7885C>T p.P2629S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866137763, COSV67545244; called by muse, mutect2, varscan2
- LAMB1 | c.566T>A p.I189N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99740063; called by muse, mutect2, varscan2
- LINGO1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV100796296; called by muse, mutect2
- LIPC | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100134251; called by muse, mutect2, varscan2
- LIPC | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100134253; called by muse, mutect2, varscan2
- LMO7 | c.740C>T p.S247F (on ENST00000357063; = p.S262F on NM_005358.5) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100412601; called by muse, mutect2, varscan2
- LOXL3 | c.665A>C p.E222A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.492); catalogued as COSV99283961; called by muse, mutect2, varscan2
- LTV1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100849553; called by muse, mutect2, varscan2
- LTV1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100849554; called by muse, mutect2, varscan2
- LYST | c.6008C>T p.P2003L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101088434; called by muse, mutect2
- LYST | c.6007C>T p.P2003S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV101088435; called by muse, mutect2
- MAGEC1 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.608); catalogued as COSV53582441; called by muse, mutect2, varscan2
- MAP1A | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100288201; called by muse, mutect2, varscan2
- MAP2 | c.839T>A p.L280* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99558285; called by muse, mutect2, varscan2
- MEIS2 | c.904C>T p.P302S (on ENST00000561208 / NM_170675.5; = p.P289S on NM_002399.3) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99575916; called by muse, mutect2
- MMD | c.111C>T p.F37= | Splice Region (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100017794; called by muse, mutect2, varscan2
- MMRN1 | c.3643C>T p.P1215S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773614750, COSV53334580, COSV53343010; called by muse, mutect2, varscan2
- MOXD1 | c.1587G>A p.W529* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as rs140134245, COSV100381299, COSV100381837; called by muse, mutect2, varscan2
- MPHOSPH10 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99731020; called by muse, mutect2, varscan2
- MUC16 | c.5263C>T p.P1755S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1421015584, COSV99064361; called by muse, mutect2, varscan2
- MUC17 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as rs866365154, COSV100071942; called by muse, mutect2, varscan2
- MUC5B | c.12623G>A p.G4208E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs755520172, COSV101500071; called by muse, mutect2, varscan2
- MYH2 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV55445459, COSV99819433; called by muse, mutect2, varscan2
- MYH2 | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99819435; called by muse, mutect2, varscan2
- N6AMT1 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100374886; called by muse, mutect2
- NAV3 | c.4232C>T p.S1411L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.976); catalogued as COSV99887654; called by muse, mutect2
- NCKAP1L | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.927); catalogued as COSV99514595; called by muse, mutect2, varscan2
- NCKAP5L | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.693); catalogued as rs1302363313, COSV100258434; called by muse, mutect2, varscan2
- NEK1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs766764559, COSV71455128; called by muse, mutect2, varscan2
- NLRC3 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100072500; called by muse, mutect2, varscan2
- NLRP1 | c.3773C>T p.S1258F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99333204; called by muse, mutect2
- NOS2 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV100569511; called by muse, mutect2
- NPHP1 | c.1207C>T p.L403F (on ENST00000393272 / NM_207181.4; = p.L404F on NM_000272.5) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100337853; called by muse, mutect2, varscan2
- NR1I2 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100561468; called by muse, mutect2
- OLFM3 | c.760-1G>A p.X254_splice (on ENST00000338858 / NM_001288821.1; = p.X234_splice on NM_058170.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100128984; called by muse, mutect2
- OLFM4 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as COSV99524211; called by muse, mutect2, varscan2
- OR11A1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV101010683; called by muse, mutect2, varscan2
- OR11H6 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751134055, COSV100209728; called by muse, mutect2, varscan2
- OR2M2 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100677187, COSV100677301; called by muse, mutect2, varscan2
- OR4C13 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV73648722; called by muse, mutect2, varscan2
- OR51E2 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101211323; called by muse, mutect2
- OR5M1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV101591535; called by muse, mutect2, varscan2
- OSBPL6 | c.2744C>T p.T915I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99506806; called by muse, mutect2, varscan2
- PALB2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs750782778, COSV99848142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAOX | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV99529699; called by muse, mutect2, varscan2
- PAX4 | c.144+1G>A p.X48_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100489987; called by muse, mutect2, varscan2
- PAXBP1 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99269076; called by muse, mutect2, varscan2
- PCDHGB3 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99532558; called by muse, mutect2, varscan2
- PCDHGC3 | c.109A>T p.I37F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as rs1414835001, COSV99338486; called by muse, mutect2, varscan2
- PCDHGC3 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV99338488; called by muse, mutect2, varscan2
- PCLO | c.2137C>T p.H713Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV61630438; called by mutect2, varscan2
- PCSK1 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.018); catalogued as COSV60737428; called by muse, mutect2, varscan2
- PDE4B | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100302532; called by muse, mutect2, varscan2
- PER3 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.468); catalogued as rs764793226, COSV100728238; called by muse, mutect2, varscan2
- PHF10 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59323682; called by muse, mutect2, varscan2
- PHLDB2 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); catalogued as COSV101208441; called by muse, mutect2, varscan2
- PHLDB2 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs1340744221, COSV101208442; called by muse, mutect2, varscan2
- PIGN | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV100715551; called by muse, mutect2, varscan2
- PIGN | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV100715552; called by muse, mutect2, varscan2
- PIM2 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.014); catalogued as COSV99900017; called by muse, mutect2, varscan2
- PIM2 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV99900018; called by muse, mutect2, varscan2
- PKDREJ | c.6163G>A p.G2055S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99478498; called by muse, mutect2
- PLCB1 | c.1757T>A p.F586Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100569648; called by muse, mutect2, varscan2
- PLCL1 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV101406815; called by muse, mutect2, varscan2
- PLEKHG4B | c.1568A>C p.E523A (on ENST00000283426; = p.E879A on NM_052909.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99359894; called by muse, mutect2, varscan2
- PPP1R16A | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as rs748499226, COSV99477443; called by muse, mutect2, varscan2
- PPP2R5C | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100159158; called by muse, mutect2, varscan2
- PRIMPOL | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV100153070; called by muse, mutect2, varscan2
- PROSER1 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.23); catalogued as COSV100612678; called by muse, mutect2, varscan2
- PSG11 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100105539; called by muse, mutect2, varscan2
- PSMC3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV100099335; called by muse, mutect2, varscan2
- PSMG1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100312976, COSV59001836; called by muse, mutect2, varscan2
- PTPRZ1 | c.4999C>T p.Q1667* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101099696; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1241C>G p.P414R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99769754, COSV99770307; called by muse, mutect2, varscan2
- RABL2A | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100905638; called by muse, mutect2, varscan2
- RIN3 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs1486466054, COSV99378692; called by muse, mutect2, varscan2
- RIOK3 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100259181; called by muse, mutect2, varscan2
- RIPK1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99454094; called by muse, mutect2, varscan2
- RNF17 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.163); catalogued as rs572750591, COSV55037735; called by muse, mutect2, varscan2
- RUNX1T1 | c.626A>T p.Q209L (on ENST00000265814 / NM_001198628.1; = p.Q182L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99749880; called by muse, mutect2
- RYR1 | c.12335C>T p.S4112L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs193922847, CM071983, COSV62087989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.3967C>T p.P1323S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs1483211829, COSV100768510; called by muse, mutect2, varscan2
- S100A5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100785888; called by muse, mutect2
- SAMD9 | c.788A>C p.H263P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV101180142, COSV66077005; called by muse, mutect2, varscan2
- SATB2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99610702; called by muse, mutect2, varscan2
- SCTR | c.487A>C p.I163L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV99191523; called by muse, mutect2, varscan2
- SENP7 | c.1377G>C p.K459N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1294046264, COSV58610592; called by muse, mutect2
- SERPINA1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs370923940; called by muse, mutect2, varscan2
- SERPINB12 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV54035739; called by muse, mutect2, varscan2
- SHANK2 | c.5314C>T p.P1772S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as rs782567869, COSV99572582; called by muse, mutect2, varscan2
- SIGLEC10 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs1338912180, COSV100218555, COSV59478756; called by muse, mutect2, varscan2
- SLA | c.316G>A p.G106S (on ENST00000338087 / NM_001045556.3; = p.G146S on NM_006748.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55095302, COSV99599429; called by muse, mutect2, varscan2
- SLC22A10 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100235553; called by muse, mutect2, varscan2
- SLCO1A2 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV100261397; called by muse, mutect2, varscan2
- SLCO1A2 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs373572811; called by muse, mutect2, varscan2
- SLFN13 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99539780; called by muse, mutect2, varscan2
- SMCHD1 | c.4454C>T p.P1485L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM154156, COSV99860861; called by muse, mutect2
- SNW1 | c.1550C>G p.P517R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99473100; called by muse, mutect2, varscan2
- SNW1 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.269); catalogued as rs1479443001, COSV99473101; called by muse, mutect2, varscan2
- SPEF2 | c.3468+1G>A p.X1156_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100606512; called by mutect2, varscan2
- SRRM2 | c.5318C>T p.S1773F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1303337649, COSV100070340; called by muse, mutect2, varscan2
- SSC4D | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.367); catalogued as rs1244716092, COSV51882138; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | PolyPhen possibly damaging (0.548); catalogued as COSV99336276; called by muse, mutect2
- STK32B | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767862829, COSV51508775; called by muse, mutect2, varscan2
- SUMF1 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99794492; called by mutect2, varscan2
- SURF2 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100914293; called by muse, mutect2
- TANC1 | c.586A>C p.N196H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV55100262; called by muse, mutect2
- TAS2R40 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101282981; called by muse, mutect2, varscan2
- TBL3 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs929661284, COSV100224731; called by muse, mutect2, varscan2
- TDRD6 | c.3370T>G p.L1124V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV100287225; called by muse, mutect2, varscan2
- TECTA | c.3736G>A p.G1246S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs200218954, COSV99878903; called by muse, mutect2, varscan2
- TECTA | c.3737G>A p.G1246D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99878909; called by muse, mutect2, varscan2
- TESMIN | c.1275A>T p.E425D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99663416; called by muse, mutect2, varscan2
- THSD7B | c.4310G>A p.W1437* (on ENST00000272643; = p.W1435* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as rs1291034873, COSV99745642; called by muse, mutect2, varscan2
- TLE1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs754927624, COSV100916261, COSV64691539; called by muse, mutect2, varscan2
- TLN2 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100168225; called by muse, mutect2, varscan2
- TLR2 | c.436T>G p.S146A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as COSV99472120; called by muse, mutect2, varscan2
- TMEM156 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1212154469, COSV100756027, COSV60744873; called by muse, mutect2, varscan2
- TMEM251 | c.376C>T p.P126S (on ENST00000415050 / NM_001098621.4; = p.P94S on NM_015676.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV99365650; called by muse, mutect2, varscan2
- TMEM63A | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100834281; called by muse, mutect2, varscan2
- TMEM63A | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.725); catalogued as COSV100834283; called by muse, mutect2, varscan2
- TNRC6B | c.3068C>T p.T1023I (on ENST00000454349 / NM_001162501.2; = p.T970I on NM_015088.3) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100109155; called by muse, mutect2
- TOX3 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as COSV99567118; called by muse, mutect2, varscan2
- TSPAN8 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV56081104; called by muse, mutect2, varscan2
- TTLL13P | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296436; called by muse, mutect2, varscan2
- TTN | c.7856G>A p.G2619D (on ENST00000591111; = p.G2573D on NM_003319.4) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | PolyPhen probably damaging (1); catalogued as rs1321051382, COSV60233936; called by muse, mutect2, varscan2
- TTN | c.7856-1G>A p.X2619_splice (on ENST00000591111; = p.X2573_splice on NM_003319.4) | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100598065; called by muse, mutect2, varscan2
- TYRO3 | c.521G>A p.W174* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV99777280; called by muse, mutect2, varscan2
- UAP1L1 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814413; called by muse, mutect2, varscan2
- UBAC1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100873758; called by muse, mutect2, varscan2
- ULK2 | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as COSV100860682; called by muse, mutect2, varscan2
- UNC13C | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV99512687; called by muse, mutect2, varscan2
- USH2A | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs202247801, COSV56323471, COSV56334875, COSV56376283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR59 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100049007; called by muse, mutect2, varscan2
- WNK4 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV99889603; called by mutect2, varscan2
- ZBBX | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as COSV100283247; called by muse, mutect2
- ZC3H15 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV61923852; called by muse, mutect2, varscan2
- ZC3H15 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100551992; called by muse, mutect2, varscan2
- ZMYM4 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV100109651; called by muse, mutect2, varscan2
- ZNF214 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV53483242, COSV99547236; called by muse, mutect2, varscan2
- ZNF214 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs1055040199, COSV99547244; called by muse, mutect2, varscan2
- ZNF281 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV99664034; called by muse, mutect2, varscan2
- ZNF287 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.251); catalogued as COSV101209336; called by muse, mutect2, varscan2
- ZNF324B | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100351546; called by muse, mutect2, varscan2
- ZNF385B | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415818; called by muse, mutect2, varscan2
- ZNF404 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100182357; called by muse, mutect2, varscan2
- ZNF431 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.021); catalogued as COSV100218531; called by muse, mutect2, varscan2
- ZNF454 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV60768110; called by muse, mutect2, varscan2
- ZNF566 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV101091269; called by muse, mutect2, varscan2
- ZNF613 | c.194C>T p.P65L (on ENST00000293471 / NM_001031721.4; = p.P29L on NM_024840.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs778350936, COSV99522849; called by muse, mutect2
- ZNF678 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs764554915, COSV59380308; called by muse, mutect2, varscan2
- ZNF709 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as rs780599968, COSV101172098; called by muse, mutect2, varscan2
- ZSCAN30 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100310048; called by muse, mutect2, varscan2
- DHX32 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FCGBP | c.11603C>T p.P3868L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- LEO1 | c.1284_1286delinsGG p.G430Efs*11 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by pindel, varscan2*
- OR2A14 | c.531_532del p.F177Lfs*2 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, varscan2*
- PCDHB9 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PCDHGB5 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- SHLD1 | c.197_198del p.I66Rfs*4 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- SPTBN2 | c.5743G>C p.A1915P | Missense Mutation (SNP) | VAF 2/19 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- SUPT5H | c.1543_1544delinsT p.P515Sfs*39 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by pindel, varscan2*
- TRBV28 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ZNF831 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA4 | c.6567C>T p.F2189= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100933045; called by muse, mutect2, varscan2
- ABCC3 | c.3504G>A p.R1168= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99558781; called by muse, mutect2, varscan2
- ADAMTSL5 | c.354C>T p.F118= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100389077; called by muse, mutect2
- ADAR | c.2139C>T p.V713= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99425595; called by muse, mutect2, varscan2
- ADCK5 | c.894C>T p.V298= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1554860687, COSV100450253; called by mutect2, varscan2
- ADGRG3 | c.1455G>A p.L485= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100342118; called by muse, mutect2, varscan2
- AFF3 | c.2142C>T p.N714= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57841742; called by muse, mutect2, varscan2
- ALG10 | c.918C>T p.L306= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99847953; called by muse, mutect2, varscan2
- ALG12 | c.1447A>C p.R483= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100427015; called by muse, mutect2, varscan2
- ALG12 | c.1446G>A p.E482= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100427016; called by muse, mutect2, varscan2
- ANK2 | c.5874G>A p.E1958= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100000100; called by muse, mutect2, varscan2
- ARGLU1 | c.210G>A p.R70= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100639745; called by muse, mutect2, varscan2
- ARHGEF16 | c.2079G>A p.V693= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV65681694; called by muse, mutect2, varscan2
- ATP6AP2 | c.177T>C p.S59= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV101011455; called by muse, mutect2, varscan2
- ATRNL1 | c.2553A>G p.E851= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100369553; called by muse, mutect2, varscan2
- AXDND1 | c.2427C>T p.L809= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100858264; called by muse, mutect2
- BDH2 | c.495C>T p.F165= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99600597; called by muse, mutect2, varscan2
- BTBD8 | c.225C>G p.V75= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV100730146, COSV61544954; called by muse, mutect2, varscan2
- C16orf70 | c.777C>T p.F259= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99531187; called by muse, mutect2, varscan2
- C9orf50 | c.661C>T p.L221= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1341138107, COSV100992306; called by muse, mutect2, varscan2
- CABP2 | c.609C>T p.L203= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53709985; called by muse, mutect2, varscan2
- CADM3 | c.597C>T p.T199= (on ENST00000368125 / NM_001127173.3; = p.T233= on NM_021189.5) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100930269; called by muse, mutect2, varscan2
- CAPN3 | c.489C>T p.F163= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100532592; called by muse, mutect2, varscan2
- CASP8AP2 | c.3747C>T p.S1249= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs376295745; called by muse, mutect2, varscan2
- CAVIN4 | c.1002C>T p.I334= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100293134; called by muse, mutect2, varscan2
- CCDC191 | c.456C>T p.T152= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs776214964, COSV99877967; called by muse, mutect2, varscan2
- CCM2 | c.393C>T p.I131= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99347564; called by muse, mutect2, varscan2
- CCR9 | c.858C>T p.I286= (on ENST00000357632 / NM_031200.3; = p.I274= on NM_006641.4) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100591610; called by muse, mutect2, varscan2
- CDC25B | c.732A>G p.E244= (on ENST00000245960 / NM_021873.3; = p.E230= on NM_004358.4) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99847656; called by muse, mutect2, varscan2
- CDR1 | c.480C>T p.S160= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs146276960, COSV100983394, COSV65164211; called by muse, mutect2, varscan2
- CEACAM1 | c.144G>A p.G48= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs1226569125, COSV99362184; called by muse, mutect2, varscan2
- CEP128 | c.1515G>A p.E505= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV55391589, COSV99823847; called by muse, mutect2, varscan2
- CNGA4 | c.1626C>T p.P542= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs560979109, COSV66005473; called by muse, mutect2, varscan2
- COG6 | c.618G>A p.T206= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs147738794; called by muse, mutect2, varscan2
- COL9A3 | c.1509C>T p.V503= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100101907; called by muse, mutect2, varscan2
- CPNE1 | c.1480C>A p.R494= (on ENST00000352393; = p.R499= on NM_003915.5) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100467115, COSV100468169; called by muse, mutect2, varscan2
- CSMD2 | c.5502C>T p.I1834= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99586883; called by muse, mutect2, varscan2
- CUBN | c.7230C>T p.Y2410= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs1206836325, COSV100912175; called by muse, mutect2, varscan2
- DACT1 | c.1830G>A p.K610= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100241635; called by muse, mutect2, varscan2
- DCAF8L1 | c.534G>A p.G178= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV101491408; called by muse, mutect2, varscan2
- DDHD1 | c.1584G>A p.V528= (on ENST00000323669; = p.V725= on NM_030637.3) | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100079148; called by muse, mutect2, varscan2
- DENND2A | c.1368C>T p.S456= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV52048645; called by muse, mutect2, varscan2
- DLC1 | c.501T>C p.A167= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1312568913, COSV99361568; called by mutect2, varscan2
- DLX1 | c.666C>T p.S222= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs374088146, COSV59395507; called by muse, mutect2
- DNAJC10 | c.27C>T p.D9= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1343024836, COSV51146863, COSV99898944; called by muse, mutect2, varscan2
- DNAJC10 | c.1341C>T p.A447= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99898948; called by muse, mutect2, varscan2
- DRP2 | c.2622C>T p.L874= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1213964843, COSV101235140; called by muse, mutect2
- DRP2 | c.2623C>T p.L875= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV101235142; called by muse, mutect2
- EIF4A2 | c.297C>T p.F99= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1275038551, COSV99961051; called by muse, mutect2, varscan2
- EMB | c.489G>A p.G163= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- ESPL1 | c.4080C>T p.V1360= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1256756503, COSV99228969; called by muse, mutect2, varscan2
- FAM83F | c.1212C>T p.V404= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100328855; called by muse, mutect2, varscan2
- FARSA | c.1056C>T p.S352= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs776029885, COSV100108693; called by muse, mutect2, varscan2
- FAT2 | c.12126G>A p.G4042= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99941908; called by muse, mutect2, varscan2
- FAT3 | c.4575C>T p.D1525= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99962782; called by muse, mutect2, varscan2
- FBXO10 | c.939C>T p.I313= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs766087542, COSV52831496; called by muse, mutect2, varscan2
- FEZF1 | c.891C>T p.F297= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100484429; called by muse, mutect2, varscan2
- FGFR1 | c.1041C>T p.I347= (on ENST00000447712 / NM_023110.3; = p.I345= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs866252086, COSV100247527; called by muse, mutect2, varscan2
- GALNT15 | c.207G>A p.L69= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100327346; called by muse, mutect2, varscan2
- GJB2 | c.378C>T p.V126= | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as COSV101241472; called by muse, mutect2
- GLIS3 | c.462C>T p.S154= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs770293029, COSV100173416; called by mutect2, varscan2
- GPR119 | c.648G>A p.R216= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV52276812; called by muse, mutect2, varscan2
- GPR63 | c.93C>T p.L31= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100013179, COSV57744350; called by muse, mutect2, varscan2
- HDC | c.1068G>A p.R356= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs866248622, COSV99983870; called by muse, mutect2, varscan2
- HGF | c.723C>T p.H241= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99735885; called by muse, mutect2, varscan2
- HINT2 | c.345C>G p.L115= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs759860704, COSV99427867, COSV99428006; called by muse, mutect2, varscan2
- HIVEP1 | c.6705C>T p.T2235= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs773947325, COSV101044810; called by muse, mutect2, varscan2
- HLA-DOA | c.246G>A p.P82= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs550573091, COSV100008116; called by muse, mutect2
- HMCN1 | c.13632C>T p.T4544= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99625154; called by muse, mutect2, varscan2
- IBA57 | c.666C>T p.H222= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100812757; called by muse, mutect2, varscan2
- IFI35 | c.474C>T p.F158= (on ENST00000415816 / NM_001330230.2; = p.F160= on NM_005533.5) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99887716; called by muse, mutect2, varscan2
- IFT172 | c.2736C>T p.S912= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99561937; called by muse, mutect2
- ITPR3 | c.879C>T p.C293= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1422029448, COSV100967008; called by muse, mutect2, varscan2
- KIR2DL4 | c.714C>T p.F238= (on ENST00000396284; = p.F199= on NM_001080770.2) | Silent (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- KLHL30 | c.1119G>A p.A373= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs771617047, COSV100014035, COSV59975479; called by muse, mutect2, varscan2
- KMT2E | c.534C>T p.R178= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV99995903; called by muse, mutect2, varscan2
- KMT2E | c.535C>A p.R179= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV99995907; called by muse, mutect2, varscan2
- KRTAP24-1 | c.435C>T p.L145= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100447340; called by muse, mutect2, varscan2
- LDLRAD4 | c.465C>T p.F155= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100762004; called by muse, mutect2, varscan2
- LINGO1 | c.693G>A p.R231= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1400726019, COSV100796298; called by muse, mutect2
- LIPE | c.1449G>A p.Q483= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs140139139; called by muse, mutect2, varscan2
- LMO7 | c.741C>T p.S247= (on ENST00000357063; = p.S262= on NM_005358.5) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100412602; called by muse, mutect2, varscan2
- LRP1B | c.225C>T p.I75= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV67186717; called by muse, mutect2, varscan2
- LYZL2 | c.528G>A p.K176= (on ENST00000375318; = p.K130= on NM_183058.3) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100940547; called by muse, mutect2, varscan2
- MAGEC1 | c.2808G>A p.T936= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs368536858, COSV53577513, COSV99596688; called by muse, mutect2, varscan2
- MCTP1 | c.1905G>A p.A635= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs571380057, COSV100386444; called by muse, mutect2, varscan2
- MMP27 | c.672C>T p.L224= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs757501720, COSV52780707, COSV99498275; called by mutect2, varscan2
- MPEG1 | c.2002C>T p.L668= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99915081; called by muse, mutect2, varscan2
- MSH3 | c.2091G>A p.G697= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99432453; called by muse, mutect2, varscan2
- N6AMT1 | c.624C>T p.V208= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100374890; called by muse, mutect2, varscan2
- NCAPG2 | c.99C>T p.F33= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs765968854, COSV99316607; called by muse, mutect2, varscan2
- NLRP1 | c.3774C>T p.S1258= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99333202; called by muse, mutect2
- OBSCN | c.6921T>G p.G2307= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99474059; called by muse, mutect2, varscan2
- OR4C13 | c.666C>T p.S222= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV101634146; called by muse, mutect2, varscan2
- OR4K15 | c.190T>C p.L64= (on ENST00000305051; = p.L40= on NM_001005486.1) | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs1409551514, COSV100520988; called by muse, mutect2, varscan2
- OSBPL6 | c.2745C>T p.T915= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs770803948, COSV99506809; called by muse, mutect2, varscan2
- OSBPL7 | c.1470C>T p.D490= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99136565; called by mutect2, varscan2
- OTUB1 | c.771C>T p.V257= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1392991029, COSV99734751; called by muse, mutect2, varscan2
- PAOX | c.1032G>A p.E344= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99529697; called by muse, mutect2, varscan2
- PCDHA9 | c.2268G>A p.Q756= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100969139; called by muse, mutect2, varscan2
- PDZRN4 | c.1506C>T p.F502= (on ENST00000402685 / NM_001164595.2; = p.F244= on NM_013377.4) | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV54192734, COSV54212469; called by muse, mutect2, varscan2
- PFKM | c.1554C>T p.L518= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100402292; called by muse, mutect2, varscan2
- PGM1 | c.1116C>T p.S372= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs1198891438, COSV100936527; called by muse, mutect2, varscan2
- PHF12 | c.2839C>T p.L947= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100241596; called by muse, mutect2, varscan2
- PLA2G5 | c.288C>T p.T96= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1011709337, COSV100908201, COSV64282753; called by muse, mutect2
- PPP1R9B | c.2316C>T p.F772= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100380638; called by muse, mutect2, varscan2
- PPP2R5C | c.795C>G p.P265= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100159154, COSV58276546; called by muse, mutect2, varscan2
- PRG4 | c.3888G>A p.T1296= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs565193791, COSV63356318; called by muse, mutect2, varscan2
- PRRT2 | c.540G>A p.E180= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99569275; called by muse, mutect2, varscan2
- PSMG1 | c.384C>T p.S128= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100312975; called by muse, mutect2, varscan2
- PTPN5 | c.972G>A p.R324= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100659721; called by muse, mutect2, varscan2
- PTPRZ1 | c.4998C>T p.F1666= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101099695; called by muse, mutect2, varscan2
- RAB8A | c.615T>G p.V205= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99507122; called by muse, mutect2
- RABL2A | c.378C>T p.I126= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100905637; called by muse, mutect2, varscan2
- RAPGEF5 | c.876G>A p.G292= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100686579; called by muse, mutect2, varscan2
- RBM5 | c.1971G>A p.P657= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs760097229, COSV61738495; called by muse, mutect2, varscan2
- RIN3 | c.1947C>T p.T649= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99378690; called by mutect2, varscan2
- RIOK3 | c.1107C>T p.A369= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs767271842, COSV100259178; called by muse, mutect2, varscan2
- RUBCN | c.195C>T p.L65= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1253559507, COSV99583385; called by muse, mutect2, varscan2
- RYR2 | c.3966C>T p.L1322= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100768509; called by muse, mutect2, varscan2
- S100A5 | c.210G>A p.K70= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100785890, COSV63296854; called by muse, mutect2
- SLAIN1 | c.828C>T p.I276= (on ENST00000466548; = p.I13= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99935028; called by muse, mutect2, varscan2
- SLC22A10 | c.309G>A p.G103= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100235552; called by muse, mutect2, varscan2
- SLC4A5 | c.1218C>T p.D406= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100697447; called by muse, mutect2, varscan2
- SLFN13 | c.309G>A p.R103= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99539779; called by muse, mutect2, varscan2
- SMPD1 | c.1425C>T p.S475= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100192410; called by muse, mutect2, varscan2
- SNX7 | c.546G>A p.R182= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100068631; called by muse, mutect2, varscan2
- SYT9 | c.216C>T p.F72= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs772136021, COSV59615123; called by muse, mutect2, varscan2
- TBL3 | c.1881C>T p.S627= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1343235401, COSV100224729; called by muse, mutect2, varscan2
- TFR2 | c.1992C>T p.L664= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs1345243339, COSV99774366; called by muse, mutect2, varscan2
- TGFBR2 | c.967C>T p.L323= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs781018006, COSV99846650; called by muse, mutect2, varscan2
- TLR3 | c.1143G>A p.L381= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99710858; called by muse, mutect2
- TMEM183A | c.402C>T p.P134= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100923821; called by muse, mutect2, varscan2
- TMPRSS6 | c.1128C>T p.A376= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100695473; called by muse, mutect2, varscan2
- TP53 | c.741C>T p.N247= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs786202448, COSV52772996, COSV52808615, COSV52847658; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRBV28 | c.246G>C p.G82= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs761018242; called by muse, mutect2, varscan2
- TSSK1B | c.900C>T p.P300= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs765421466, COSV101180989, COSV66816083; called by muse, mutect2, varscan2
- TTN | c.1671G>A p.Q557= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100597262; called by muse, mutect2, varscan2
- UBQLN3 | c.1254G>A p.E418= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100293408; called by muse, mutect2, varscan2
- UNC13C | c.606C>T p.T202= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99512691; called by muse, mutect2, varscan2
- UPK1B | c.21T>A p.T7= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99953530; called by muse, mutect2, varscan2
- USP5 | c.2226G>A p.L742= (on ENST00000229268 / NM_001098536.2; = p.L719= on NM_003481.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99978252; called by muse, mutect2, varscan2
- WNT7B | c.291C>T p.L97= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100254806; called by muse, mutect2, varscan2
- ZGRF1 | c.6228C>T p.L2076= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101500564; called by muse, mutect2, varscan2
- ZNF281 | c.735G>A p.L245= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99664035; called by muse, mutect2, varscan2
- ZNF324B | c.492C>T p.S164= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100351548; called by muse, mutect2, varscan2
- ZNF385D | c.114C>T p.P38= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV55747346; called by muse, mutect2, varscan2
- ZNF404 | c.240C>T p.N80= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100182363; called by muse, mutect2, varscan2
- ZNF709 | c.1425C>T p.P475= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV67194267; called by muse, mutect2, varscan2
- AK5 | c.699+15895C>T | Intron (SNP) | VAF 11/42 reads (26%) | catalogued as rs770177303, COSV100481373; called by muse, mutect2, varscan2
